Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9KH, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9KH-01A (Primary Tumor).

ICD-O-3
Carcinoma, papillary renal cell 8260/3
Site: (R) Kidney NOS C64.9
JAS 6/13/14

3.8 cm maximum dimension, moderately differentiated Papillary renal Cell Carcinoma. Notes
glomerulosclerosis, interstitial nephritis and massive arteriosclerosis. Resection margins are tumor
free.

pTNM classification (edition 2002)

Stage: pT1a, pNX, pMX

Grade: GII

Laterality = (R)

Source: NCI Genomic Data Commons file e93655b9-9cec-4c0e-a976-f8d800ab0532 (TCGA-5P-A9KH.7F7348FB-2484-4E77-83F2-B26C72CF6F3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).